Somatic mutation profile of tumor specimen C3N-06993-01 (aliquot CPT0465600006) from CPTAC case C3N-06993, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 70.7 years (25,808 days).
Specimen C3N-06993-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b9497d53-070e-45b7-8c6b-522e514cd654.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-06993-31 (Blood Derived Normal), aliquot CPT0465720006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ce862cd2-e43d-438d-a2e1-fd4d013d2b58

The open-access MAF lists 200 somatic variants for this specimen: 141 protein-altering or splice-affecting, 56 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 129, Silent 56, Nonsense Mutation 6, Frame Shift Del 4, Intron 3, Splice Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCD1 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 183/467 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1131691954, CM960037; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 169/395 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 113/163 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912652, CM900213, COSV52684909, COSV52740428, COSV52828352; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRF1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 387/689 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV99347510; called by muse, mutect2, varscan2
- AGBL1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 157/752 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.072); catalogued as rs762731518; called by muse, mutect2, varscan2
- AMDHD1 | c.404T>C p.F135S | Missense Mutation (SNP) | VAF 232/535 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs551304292; called by muse, mutect2, varscan2
- ANKRD18B | c.1930T>A p.F644I | Missense Mutation (SNP) | VAF 151/383 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.316); catalogued as rs572739753; called by muse, mutect2, varscan2
- ARID3B | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 144/568 reads (25%) | catalogued as rs1444993007; called by muse, mutect2, varscan2
- BIN2 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 127/301 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs1291691495; called by muse, mutect2, varscan2
- C20orf194 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 77/185 reads (42%) | catalogued as COSV99330220; called by muse, mutect2, varscan2
- CCDC185 | c.1133G>A p.R378H | Missense Mutation (SNP) | VAF 234/539 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as rs777942218; called by muse, mutect2, varscan2
- CES1 | c.846G>A p.M282I | Missense Mutation (SNP) | VAF 184/538 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.015); catalogued as COSV62090696; called by muse, mutect2, varscan2
- CFAP57 | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 100/276 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs756372048, COSV65263826; called by muse, mutect2, varscan2
- CFTR | c.1822G>A p.E608K | Missense Mutation (SNP) | VAF 125/305 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV50041533; called by muse, mutect2, varscan2
- CREB5 | c.454C>T p.R152C (on ENST00000357727 / NM_182898.4; = p.R145C on NM_004904.3) | Missense Mutation (SNP) | VAF 121/275 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs374897586, COSV63218644; called by muse, mutect2, varscan2
- DAB1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 94/233 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV59725348; called by muse, mutect2, varscan2
- DALRD3 | c.727G>A p.D243N (on ENST00000341949 / NM_001009996.3; = p.D76N on NM_018114.5) | Missense Mutation (SNP) | VAF 140/378 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.526); catalogued as rs756920547, COSV58247792; called by muse, mutect2, varscan2
- DNAH5 | c.8015C>T p.T2672M | Missense Mutation (SNP) | VAF 86/232 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1358728493, COSV99445573; called by muse, mutect2, varscan2
- DSCAM | c.1979C>T p.S660L | Missense Mutation (SNP) | VAF 192/261 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.146); catalogued as rs1457401217; called by muse, mutect2, varscan2
- FSTL5 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 125/322 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs779449215, COSV60198887; called by muse, mutect2, varscan2
- GAS7 | c.587C>T p.T196I (on ENST00000432992 / NM_201433.2; = p.T56I on NM_003644.3) | Missense Mutation (SNP) | VAF 113/154 reads (73%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as COSV100097375; called by muse, varscan2
- GRHPR | c.469G>A p.G157S | Missense Mutation (SNP) | VAF 200/435 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs774233908, COSV58944706; called by muse, mutect2, varscan2
- HMX1 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 166/460 reads (36%) | PolyPhen possibly damaging (0.691); catalogued as rs1425913097; called by muse, mutect2, varscan2
- HNRNPCL2 | c.464G>T p.R155M | Missense Mutation (SNP) | VAF 203/594 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); catalogued as rs1224373257; called by muse, varscan2
- HSPA8 | c.746A>G p.H249R | Missense Mutation (SNP) | VAF 134/178 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.102); catalogued as COSV57086647; called by muse, mutect2, varscan2
- IFT88 | c.2092G>A p.E698K (on ENST00000319980 / NM_001318493.2; = p.E689K on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.137); catalogued as COSV100179494; called by muse, mutect2, varscan2
- IL9 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 79/110 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1284023671; called by muse, mutect2, varscan2
- IQCN | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 276/938 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV66572824; called by muse, mutect2
- ISL1 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 177/521 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV57932277; called by muse, mutect2, varscan2
- ITPK1 | c.326C>T p.S109F | Missense Mutation (SNP) | VAF 207/456 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50894945; called by muse, mutect2, varscan2
- KRT1 | c.1540G>A p.G514R | Missense Mutation (SNP) | VAF 218/544 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.691); catalogued as COSV52866953; called by muse, mutect2, varscan2
- MAG | c.1273C>T p.R425* | Nonsense Mutation (SNP) | VAF 399/682 reads (59%) | catalogued as COSV100728046, COSV62699261; called by muse, mutect2, varscan2
- NEB | c.8039G>A p.R2680Q | Missense Mutation (SNP) | VAF 158/367 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.254); catalogued as rs201746137; ClinVar: uncertain significance; called by muse, varscan2
- NLRP11 | c.1993C>T p.R665C | Missense Mutation (SNP) | VAF 115/271 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs141366900; called by muse, mutect2, varscan2
- OR1S2 | c.736G>A p.G246R | Missense Mutation (SNP) | VAF 229/505 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.585); catalogued as COSV100224041; called by muse, varscan2
- OR4Q3 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 144/971 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100057187; called by muse, mutect2, varscan2
- PCDHB13 | c.1486C>A p.P496T | Missense Mutation (SNP) | VAF 35/518 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.052); catalogued as rs1554287968; called by muse, mutect2
- PCDHB5 | c.209G>A p.G70E | Missense Mutation (SNP) | VAF 182/238 reads (76%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.085); catalogued as COSV50672617; called by muse, mutect2, varscan2
- PCSK9 | c.1492G>A p.E498K | Missense Mutation (SNP) | VAF 153/347 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.432); catalogued as rs145468572, CM1212016; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PDK3 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 156/388 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.403); catalogued as COSV64794556; called by muse, mutect2, varscan2
- PRAMEF12 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 209/435 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100742977, COSV100743171; called by muse, mutect2, varscan2
- RD3 | c.233G>A p.R78Q | Missense Mutation (SNP) | VAF 212/477 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.963); catalogued as rs199896612; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGCA | c.949G>A p.E317K | Missense Mutation (SNP) | VAF 194/464 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56248510; called by muse, mutect2, varscan2
- SHANK1 | c.5986C>T p.R1996C | Missense Mutation (SNP) | VAF 301/671 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs1391997547; called by muse, mutect2, varscan2
- SLC38A11 | c.821G>A p.G274E (on ENST00000409149 / NM_001351539.1; = p.G252E on NM_173512.2) | Missense Mutation (SNP) | VAF 94/222 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0.033); catalogued as rs1260772268; called by muse, mutect2, varscan2
- TBCD | c.2804C>T p.P935L | Missense Mutation (SNP) | VAF 202/501 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.053); catalogued as COSV62806625; called by muse, mutect2, varscan2
- TNR | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 192/456 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.323); catalogued as COSV54876921; called by muse, mutect2, varscan2
- TP63 | c.490G>A p.A164T | Missense Mutation (SNP) | VAF 214/797 reads (27%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.637); catalogued as rs765564666, COSV53201487; called by muse, mutect2, varscan2
- TRPC7 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 165/223 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs551264578, COSV61461425; called by muse, mutect2, varscan2
- TTLL9 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 160/569 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs753929489, COSV60594490; called by muse, mutect2, varscan2
- TTN | c.6244G>A p.E2082K (on ENST00000591111; = p.E2036K on NM_003319.4) | Missense Mutation (SNP) | VAF 234/315 reads (74%) | PolyPhen probably damaging (0.994); catalogued as rs750064248, COSV60146579; called by muse, mutect2, varscan2
- UBQLNL | c.37C>A p.Q13K | Missense Mutation (SNP) | VAF 133/186 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as COSV66493042, COSV66493720; called by muse, mutect2, varscan2
- UNC13C | c.5794G>T p.V1932F | Missense Mutation (SNP) | VAF 62/171 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs771705012; called by muse, mutect2, varscan2
- USP51 | c.268C>T p.R90C | Missense Mutation (SNP) | VAF 262/616 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.063); catalogued as rs772523926; called by muse, mutect2, varscan2
- UTS2B | c.322C>T p.P108S | Missense Mutation (SNP) | VAF 358/546 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV61279854; called by muse, mutect2, varscan2
- VBP1 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 113/287 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.589); catalogued as COSV53972484; called by muse, mutect2, varscan2
- VPS9D1 | c.1232C>T p.A411V | Missense Mutation (SNP) | VAF 174/223 reads (78%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs776117646, COSV66994517; called by muse, mutect2, varscan2
- ZBTB33 | c.1772C>T p.S591F | Missense Mutation (SNP) | VAF 200/277 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV58533282; called by muse, mutect2, varscan2
- ZHX1 | c.2135G>A p.R712H | Missense Mutation (SNP) | VAF 215/653 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV52877496; called by muse, mutect2, varscan2
- ZNF609 | c.371G>A p.R124H | Missense Mutation (SNP) | VAF 276/590 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs369004534, COSV58581553; called by muse, mutect2, varscan2
- ZNF81 | c.1469G>A p.R490K | Missense Mutation (SNP) | VAF 200/505 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.496); catalogued as COSV58574992; called by muse, mutect2, varscan2
- ABCC9 | c.4037G>A p.G1346D | Missense Mutation (SNP) | VAF 166/408 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AHRR | c.1789C>T p.H597Y | Missense Mutation (SNP) | VAF 233/615 reads (38%) | SIFT tolerated (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- APOBEC1 | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 138/364 reads (38%) | called by muse, mutect2
- ATRX | c.3272del p.K1091Rfs*27 | Frame Shift Del (DEL) | VAF 227/664 reads (34%) | called by mutect2, pindel, varscan2
- C7orf61 | c.335C>T p.S112F | Missense Mutation (SNP) | VAF 168/422 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACHD1 | c.1638T>G p.F546L | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- CACNA1E | c.6040C>T p.P2014S (on ENST00000367573 / NM_001205293.3; = p.P1971S on NM_000721.4) | Missense Mutation (SNP) | VAF 128/306 reads (42%) | SIFT tolerated (0.55); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CD163L1 | c.3637C>T p.P1213S | Missense Mutation (SNP) | VAF 218/453 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CDC37L1 | c.353_356del p.V118Efs*54 | Frame Shift Del (DEL) | VAF 92/417 reads (22%) | called by mutect2, pindel, varscan2
- CDK15 | c.493C>T p.H165Y (on ENST00000652192 / NM_001366386.2; = p.H114Y on NM_139158.2) | Missense Mutation (SNP) | VAF 127/343 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CELSR3 | c.3092C>T p.S1031L | Missense Mutation (SNP) | VAF 229/505 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- CHD3 | c.3915G>C p.E1305D | Missense Mutation (SNP) | VAF 121/151 reads (80%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CMKLR1 | c.26A>T p.N9I (on ENST00000312143 / NM_001142344.2; = p.N7I on NM_004072.3) | Missense Mutation (SNP) | VAF 117/285 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- CNGA3 | c.1855G>A p.A619T | Missense Mutation (SNP) | VAF 258/523 reads (49%) | SIFT deleterious (0.03); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- COL5A3 | c.2422C>T p.P808S | Missense Mutation (SNP) | VAF 136/521 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- CTPS2 | c.689T>A p.I230N | Missense Mutation (SNP) | VAF 210/509 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DACT2 | c.2187G>A p.W729* | Nonsense Mutation (SNP) | VAF 241/306 reads (79%) | called by muse, mutect2, varscan2
- DOCK3 | c.3643A>G p.K1215E | Missense Mutation (SNP) | VAF 131/346 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- DST | c.14521C>T p.L4841F (on ENST00000361203 / NM_001374722.1; = p.L2429F on NM_015548.5) | Missense Mutation (SNP) | VAF 113/294 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DTHD1 | c.2014G>A p.D672N (on ENST00000456874; = p.D507N on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 148/296 reads (50%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ECE1 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 178/445 reads (40%) | SIFT tolerated (0.43); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- FA2H | c.626C>A p.A209E | Missense Mutation (SNP) | VAF 151/188 reads (80%) | SIFT tolerated (0.14); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM47A | c.842A>T p.E281V | Missense Mutation (SNP) | VAF 20/724 reads (3%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.607); called by muse, mutect2
- FLVCR2 | c.773G>A p.G258E | Missense Mutation (SNP) | VAF 157/394 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- FREM2 | c.5771C>G p.T1924R | Missense Mutation (SNP) | VAF 136/306 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- FYB1 | c.920G>A p.G307E | Missense Mutation (SNP) | VAF 209/271 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- GFRA2 | c.548C>T p.S183F | Missense Mutation (SNP) | VAF 214/280 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- GPR158 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 254/630 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GRHPR | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 182/394 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- HECTD4 | c.9652C>T p.H3218Y | Missense Mutation (SNP) | VAF 232/545 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.396); called by muse, mutect2, varscan2
- HIVEP2 | c.2785C>A p.Q929K | Missense Mutation (SNP) | VAF 15/351 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.32); called by muse, mutect2
- HTR5A | c.38C>A p.S13Y | Missense Mutation (SNP) | VAF 147/593 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by mutect2, varscan2
- IFFO1 | c.1417T>A p.Y473N (on ENST00000396840 / NM_001330324.2; = p.Y476N on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/318 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- INHBB | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 158/383 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); called by muse, mutect2, varscan2
- KCTD3 | c.1693C>T p.Q565* | Nonsense Mutation (SNP) | VAF 187/463 reads (40%) | called by muse, mutect2, varscan2
- KIFC3 | c.2035G>C p.E679Q | Missense Mutation (SNP) | VAF 156/604 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KLHL4 | c.1825G>C p.G609R | Missense Mutation (SNP) | VAF 271/617 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- KMT2A | c.7293dup p.S2432Ifs*3 | Frame Shift Ins (INS) | VAF 108/183 reads (59%) | called by mutect2, pindel, varscan2
- KMT2B | c.3611_3612del p.C1204Ffs*19 | Frame Shift Del (DEL) | VAF 371/801 reads (46%) | called by mutect2, pindel, varscan2
- LBP | c.1012G>A p.E338K | Missense Mutation (SNP) | VAF 176/661 reads (27%) | SIFT tolerated (0.42); PolyPhen benign (0.241); called by muse, mutect2
- LILRB1 | c.38T>C p.L13P | Missense Mutation (SNP) | VAF 227/636 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LINGO2 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 150/369 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- MAGI2 | c.2494C>T p.P832S | Missense Mutation (SNP) | VAF 205/456 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MANEA | c.719A>G p.Y240C | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.42); called by muse, mutect2, varscan2
- MGAM2 | c.2912C>T p.S971F | Missense Mutation (SNP) | VAF 187/1065 reads (18%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- MUC16 | c.23386C>T p.P7796S | Missense Mutation (SNP) | VAF 194/657 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- MVB12A | c.596G>A p.R199K | Missense Mutation (SNP) | VAF 377/631 reads (60%) | SIFT tolerated (0.43); PolyPhen benign (0.353); called by muse, mutect2, varscan2
- NDOR1 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 196/455 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- NDST4 | c.587A>G p.N196S | Missense Mutation (SNP) | VAF 196/482 reads (41%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- NEB | c.8120C>T p.P2707L | Missense Mutation (SNP) | VAF 130/290 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.536); called by muse, varscan2
- NPIPB13 | c.899del p.N300Ifs*287 | Frame Shift Del (DEL) | VAF 113/437 reads (26%) | called by mutect2, pindel, varscan2
- NRK | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 124/168 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- PHC3 | c.818C>T p.P273L (on ENST00000494943 / NM_001308116.2; = p.P285L on NM_024947.4) | Missense Mutation (SNP) | VAF 190/244 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- POMT2 | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 246/539 reads (46%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRAMEF14 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 50/127 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- PROK1 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 184/444 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PSG9 | c.716T>G p.L239R | Missense Mutation (SNP) | VAF 251/442 reads (57%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PTPRD | c.3265G>A p.G1089R | Missense Mutation (SNP) | VAF 196/460 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- PYGM | c.1975C>T p.P659S | Missense Mutation (SNP) | VAF 91/205 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RAE1 | c.107C>T p.S36L | Missense Mutation (SNP) | VAF 226/362 reads (62%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- RALGAPA1 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- RALGAPA1 | c.706G>A p.G236R | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RP1 | c.2873G>A p.G958E | Missense Mutation (SNP) | VAF 305/546 reads (56%) | SIFT tolerated (0.4); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- RRNAD1 | c.493G>A p.G165S | Missense Mutation (SNP) | VAF 108/272 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- SEMA5A | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 167/435 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- SH3TC1 | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 267/614 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.433); called by muse, mutect2, varscan2
- SLC13A3 | c.1592C>T p.S531F | Missense Mutation (SNP) | VAF 302/546 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC25A27 | c.463A>G p.M155V | Missense Mutation (SNP) | VAF 318/541 reads (59%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- SLC2A7 | c.691G>A p.G231R | Missense Mutation (SNP) | VAF 152/369 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.2); called by muse, mutect2, varscan2
- SLC6A16 | c.451C>A p.L151M | Missense Mutation (SNP) | VAF 156/387 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- SMOC2 | c.375C>A p.H125Q | Missense Mutation (SNP) | VAF 64/288 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPAM1 | c.1375A>G p.I459V | Missense Mutation (SNP) | VAF 196/452 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TBCK | c.382-4_382-1del p.X128_splice | Splice Site (DEL) | VAF 76/182 reads (42%) | called by mutect2, pindel, varscan2
- TREML4 | c.85C>T p.H29Y | Missense Mutation (SNP) | VAF 302/481 reads (63%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- UNC13D | c.331T>A p.F111I | Missense Mutation (SNP) | VAF 212/459 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- USP33 | c.450T>A p.F150L | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2, varscan2
- YWHAZ | c.173C>T p.S58F | Missense Mutation (SNP) | VAF 184/658 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZAN | c.7102G>A p.V2368M | Missense Mutation (SNP) | VAF 188/398 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- ZNF225 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 178/469 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- ZNF512 | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 167/415 reads (40%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADGRG4 | c.1764C>T p.I588= | Silent (SNP) | VAF 250/591 reads (42%) | called by muse, mutect2, varscan2
- ARHGAP29 | c.450C>T p.F150= | Silent (SNP) | VAF 92/258 reads (36%) | catalogued as COSV53116712; called by muse, mutect2, varscan2
- ATP13A5 | c.327C>T p.S109= | Silent (SNP) | VAF 388/650 reads (60%) | catalogued as rs773665312, COSV60872453; called by muse, mutect2, varscan2
- ATP8B2 | c.1500C>T p.F500= (on ENST00000672630; = p.F467= on NM_001367934.1 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 177/458 reads (39%) | called by muse, mutect2, varscan2
- CADPS2 | c.2817G>A p.V939= | Silent (SNP) | VAF 189/439 reads (43%) | catalogued as COSV57348878; called by muse, mutect2, varscan2
- CCDC188 | c.945G>A p.R315= | Silent (SNP) | VAF 187/422 reads (44%) | called by muse, mutect2, varscan2
- CCN1 | c.723G>A p.K241= | Silent (SNP) | VAF 206/501 reads (41%) | called by muse, mutect2, varscan2
- CELF5 | c.699G>A p.L233= | Silent (SNP) | VAF 451/763 reads (59%) | catalogued as rs1218693218; called by muse, mutect2, varscan2
- CHFR | c.1509G>A p.P503= (on ENST00000432561 / NM_001161345.1; = p.P462= on NM_018223.2) | Silent (SNP) | VAF 172/394 reads (44%) | catalogued as rs142511371; called by muse, mutect2, varscan2
- CMKLR1 | c.27C>T p.N9= (on ENST00000312143 / NM_001142344.2; = p.N7= on NM_004072.3) | Silent (SNP) | VAF 117/284 reads (41%) | called by muse, mutect2, varscan2
- CNGB1 | c.1818C>T p.A606= | Silent (SNP) | VAF 140/361 reads (39%) | catalogued as rs371170952; called by muse, mutect2, varscan2
- COL17A1 | c.859C>T p.L287= | Silent (SNP) | VAF 183/256 reads (71%) | called by muse, mutect2, varscan2
- DALRD3 | c.726G>A p.E242= (on ENST00000341949 / NM_001009996.3; = p.E75= on NM_018114.5) | Silent (SNP) | VAF 139/376 reads (37%) | catalogued as rs766656996; called by muse, mutect2, varscan2
- FAT4 | c.14949G>A p.V4983= | Silent (SNP) | VAF 112/278 reads (40%) | catalogued as rs751811552; called by muse, mutect2, varscan2
- FBN2 | c.6699G>A p.G2233= | Silent (SNP) | VAF 218/262 reads (83%) | called by muse, mutect2, varscan2
- FBN3 | c.5871C>T p.P1957= | Silent (SNP) | VAF 162/501 reads (32%) | called by muse, mutect2, varscan2
- FBXL7 | c.1173C>T p.D391= | Silent (SNP) | VAF 214/505 reads (42%) | catalogued as rs1465657697; called by muse, mutect2, varscan2
- GAS7 | c.588C>T p.T196= (on ENST00000432992 / NM_201433.2; = p.T56= on NM_003644.3) | Silent (SNP) | VAF 116/154 reads (75%) | catalogued as rs772183594, COSV60440569; called by muse, varscan2
- GLRA2 | c.588G>A p.T196= | Silent (SNP) | VAF 128/316 reads (41%) | catalogued as rs113271440, COSV54338260, COSV54345780; called by muse, mutect2, varscan2
- GRB7 | c.729G>A p.R243= | Silent (SNP) | VAF 201/502 reads (40%) | catalogued as COSV58447262; called by muse, mutect2, varscan2
- HIPK1 | c.2619C>T p.P873= | Silent (SNP) | VAF 198/436 reads (45%) | catalogued as rs760167553; called by muse, mutect2, varscan2
- HMX1 | c.510C>T p.A170= | Silent (SNP) | VAF 148/427 reads (35%) | catalogued as rs988212260; called by muse, varscan2
- HNRNPM | c.1194C>T p.V398= | Silent (SNP) | VAF 434/714 reads (61%) | catalogued as COSV99725622; called by muse, mutect2, varscan2
- IDUA | c.780C>T p.S260= | Silent (SNP) | VAF 189/432 reads (44%) | called by muse, mutect2, varscan2
- IGHV7-81 | c.144C>T p.F48= | Silent (SNP) | VAF 166/216 reads (77%) | catalogued as rs778976578; called by muse, mutect2, varscan2
- KATNB1 | c.402C>T p.I134= | Silent (SNP) | VAF 127/499 reads (25%) | called by muse, mutect2, varscan2
- KCNH5 | c.2850C>T p.A950= | Silent (SNP) | VAF 182/427 reads (43%) | called by muse, mutect2, varscan2
- KCP | c.4461C>T p.D1487= (on ENST00000620378; = p.D1611= on NM_001366122.1) | Silent (SNP) | VAF 475/779 reads (61%) | catalogued as COSV99926015; called by muse, mutect2, varscan2
- KSR2 | c.2154G>A p.R718= | Silent (SNP) | VAF 169/397 reads (43%) | called by muse, mutect2, varscan2
- LHX1 | c.1062G>A p.S354= | Silent (SNP) | VAF 343/738 reads (46%) | called by muse, varscan2
- LILRA4 | c.21C>T p.S7= | Silent (SNP) | VAF 273/608 reads (45%) | called by muse, mutect2, varscan2
- LY86 | c.477C>T p.I159= | Silent (SNP) | VAF 326/381 reads (86%) | catalogued as rs914583696; called by muse, mutect2, varscan2
- MECP2 | c.855G>A p.K285= | Silent (SNP) | VAF 194/468 reads (41%) | called by mutect2, varscan2
- MLLT6 | c.2562C>T p.A854= | Silent (SNP) | VAF 30/908 reads (3%) | called by muse, mutect2
- MPG | c.192G>A p.P64= | Silent (SNP) | VAF 494/586 reads (84%) | catalogued as rs1013660133; called by muse, varscan2
- NUP85 | c.225C>T p.S75= | Silent (SNP) | VAF 178/378 reads (47%) | called by muse, mutect2, varscan2
- OR2G3 | c.411C>T p.N137= | Silent (SNP) | VAF 246/549 reads (45%) | called by muse, mutect2, varscan2
- OR2T3 | c.744C>T p.S248= | Silent (SNP) | VAF 311/945 reads (33%) | catalogued as rs968772431, COSV62082857; called by muse, mutect2, varscan2
- PARD3 | c.3387A>G p.Q1129= | Silent (SNP) | VAF 176/382 reads (46%) | called by muse, mutect2, varscan2
- PCDH15 | c.4380C>T p.L1460= | Silent (SNP) | VAF 98/137 reads (72%) | catalogued as COSV57331347; called by muse, mutect2, varscan2
- PI4KA | c.1221C>T p.F407= | Silent (SNP) | VAF 145/368 reads (39%) | called by muse, mutect2, varscan2
- PKD1L1 | c.4212G>A p.Q1404= | Silent (SNP) | VAF 207/418 reads (50%) | called by muse, mutect2, varscan2
- PRAMEF11 | c.765G>A p.K255= | Silent (SNP) | VAF 269/430 reads (63%) | catalogued as rs775264972; called by muse, mutect2, varscan2
- RDH8 | c.417C>T p.V139= (on ENST00000651512; = p.V119= on NM_015725.4) | Silent (SNP) | VAF 368/619 reads (59%) | called by muse, mutect2, varscan2
- RENBP | c.1233C>T p.P411= | Silent (SNP) | VAF 112/241 reads (46%) | catalogued as rs1426634019; called by muse, mutect2, varscan2
- RHPN1 | c.1371G>A p.E457= | Silent (SNP) | VAF 387/636 reads (61%) | called by muse, mutect2, varscan2
- RORC | c.1209C>T p.F403= | Silent (SNP) | VAF 147/354 reads (42%) | catalogued as rs1281277876, COSV100562087; called by muse, mutect2, varscan2
- SALL4 | c.1098C>T p.I366= | Silent (SNP) | VAF 634/904 reads (70%) | catalogued as rs1279871550; called by muse, mutect2, varscan2
- SLC35E4 | c.1026G>A p.R342= | Silent (SNP) | VAF 152/512 reads (30%) | called by muse, mutect2, varscan2
- SLC5A2 | c.1758G>A p.Q586= | Silent (SNP) | VAF 124/294 reads (42%) | catalogued as rs746724730, COSV57890100; called by muse, mutect2, varscan2
- SPOCD1 | c.177C>T p.I59= | Silent (SNP) | VAF 278/578 reads (48%) | catalogued as rs1454790087, COSV57097308; called by muse, mutect2, varscan2
- SSX5 | c.408G>A p.G136= (on ENST00000347757 / NM_175723.1; = p.G177= on NM_021015.4) | Silent (SNP) | VAF 159/360 reads (44%) | catalogued as COSV100308822; called by muse, mutect2, varscan2
- SWT1 | c.1516C>T p.L506= | Silent (SNP) | VAF 107/246 reads (43%) | catalogued as COSV100833437; called by muse, mutect2, varscan2
- TOR4A | c.1167C>T p.A389= | Silent (SNP) | VAF 263/583 reads (45%) | called by muse, mutect2, varscan2
- ZFHX3 | c.6327C>T p.T2109= | Silent (SNP) | VAF 227/526 reads (43%) | catalogued as rs1049945729; called by muse, mutect2, varscan2
- ZNF804A | c.3294C>T p.I1098= | Silent (SNP) | VAF 156/197 reads (79%) | catalogued as rs529777750, COSV56444355; called by muse, mutect2, varscan2
- KIFC3 | c.316-2695C>T | Intron (SNP) | VAF 214/828 reads (26%) | catalogued as rs1555611042; called by muse, mutect2, varscan2
- PGC | c.648-583G>A | Intron (SNP) | VAF 156/552 reads (28%) | called by muse, mutect2, varscan2
- PNKD | c.237-16493_237-16483dup | Intron (INS) | VAF 68/270 reads (25%) | called by mutect2, varscan2
